Somatic mutation profile of tumor specimen TCGA-24-1474-01A (aliquot TCGA-24-1474-01A-01W-0551-08) from TCGA case TCGA-24-1474, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,902 days).
Specimen TCGA-24-1474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15592f9e-44dc-4230-af67-628db27c80f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1474-10A (Blood Derived Normal), aliquot TCGA-24-1474-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f76a78-0e0c-4ad6-ae30-a9a491cbbf2a

The open-access MAF lists 72 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 11, Nonsense Mutation 5, RNA 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 531/589 reads (90%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs80263613, CM163996; called by muse, varscan2
- ADH1B | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 126/511 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59297463; called by muse, mutect2, varscan2
- AGPAT1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1256689246, COSV100421696; called by muse, mutect2
- ATP11C | c.1709C>G p.S570W | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759958294, COSV59568416; called by muse, mutect2, varscan2
- BHMT | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as rs1045603041, COSV57155963; called by muse, mutect2, varscan2
- BPIFB6 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 197/669 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs765631164, COSV62754896, COSV62755942; called by muse, mutect2, varscan2
- C11orf94 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53797264, COSV53798909; called by mutect2, varscan2
- CACHD1 | c.3423G>A p.M1141I | Missense Mutation (SNP) | VAF 81/496 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.48); catalogued as rs766385050, COSV51556651; called by muse, mutect2, varscan2
- CFAP251 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 76/348 reads (22%) | catalogued as COSV56612914; called by muse, mutect2, varscan2
- CPAMD8 | c.3809G>A p.R1270H (on ENST00000651564; = p.R1223H on NM_015692.5) | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs202014738, COSV71596884; called by muse, mutect2, varscan2
- CPZ | c.608G>A p.R203H (on ENST00000360986 / NM_001014447.3; = p.R192H on NM_003652.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs376200702, COSV59924215; called by mutect2, varscan2
- CYB5D2 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs770028748, COSV56801349; called by muse, mutect2, varscan2
- DOLK | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV58281445; called by muse, mutect2, varscan2
- FAM200A | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs937143169, COSV68808517; called by mutect2, varscan2
- FBXO44 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs758615313, COSV52354739; called by muse, mutect2, varscan2
- FLG | c.2155A>G p.S719G | Missense Mutation (SNP) | VAF 202/1364 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs1265308092, COSV100911970; called by muse, varscan2
- GABRE | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs758332176, COSV64820388; called by muse, mutect2, varscan2
- IL1RAPL2 | c.997G>C p.V333L | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100781799; called by muse, mutect2
- INPP5B | c.427T>A p.W143R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65958191; called by muse, mutect2
- IQSEC1 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs763569888, COSV56225905; called by muse, mutect2, varscan2
- KCNN4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53456274; called by muse, mutect2, varscan2
- KEAP1 | c.567C>G p.N189K | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.136); catalogued as COSV50361686; called by muse, mutect2
- KRTAP27-1 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV67001405; called by muse, mutect2, varscan2
- LRRC75A | c.619G>C p.V207L (on ENST00000470794 / NM_001113567.3; = p.R168P on NM_207387.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV63359156; called by muse, mutect2, varscan2
- LRRIQ3 | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100599194; called by muse, mutect2, varscan2
- MAP2 | c.5033G>C p.G1678A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52298683; called by muse, mutect2
- MATN4 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | PolyPhen probably damaging (0.999); catalogued as rs1420816736, COSV59214825; called by muse, mutect2, varscan2
- MET | c.714A>T p.L238F | Missense Mutation (SNP) | VAF 93/670 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59264765; called by muse, mutect2, varscan2
- MLXIP | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59836651; called by muse, mutect2, varscan2
- MORC2 | c.2206C>T p.R736W (on ENST00000397641 / NM_001303256.3; = p.R674W on NM_014941.3) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs767451837, COSV53200428; called by muse, mutect2, varscan2
- MUC3A | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 92/471 reads (20%) | SIFT deleterious, low confidence (0); catalogued as rs767301138, COSV100115183; called by muse, mutect2, varscan2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 811/919 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, varscan2
- MYO1H | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 411/1899 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100183857, COSV60446608; called by muse, mutect2, varscan2
- NCR1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs369920502; called by muse, mutect2, varscan2
- OR51B2 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV60917134; called by muse, mutect2, varscan2
- OR5AP2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57258054, COSV57258071; called by muse, mutect2, varscan2
- PHACTR2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772695389, COSV59855663; called by muse, mutect2, varscan2
- POP5 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV58046683; called by muse, mutect2, varscan2
- RTP1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.163); catalogued as rs772437664, COSV56617613; called by muse, mutect2, varscan2
- SERINC1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV60102459; called by muse, mutect2, varscan2
- SESTD1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100091017, COSV58931951; called by muse, mutect2, varscan2
- SLC16A14 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 46/262 reads (18%) | catalogued as COSV54619761; called by muse, varscan2
- SLC17A2 | c.878T>G p.L293R | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV55353427; called by muse, mutect2, varscan2
- SLC4A7 | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 69/446 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.849); catalogued as COSV55399887; called by muse, mutect2, varscan2
- SLC9C1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as rs776718397, COSV59890132; called by muse, mutect2
- SLITRK4 | c.2498C>A p.A833D | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62025057; called by muse, mutect2, varscan2
- SMARCA1 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 81/197 reads (41%) | catalogued as COSV64412783; called by muse, mutect2, varscan2
- STAB2 | c.5785C>A p.P1929T | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV66342463; called by muse, mutect2, varscan2
- TAF3 | c.2117A>G p.K706R | Missense Mutation (SNP) | VAF 62/75 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60208617; called by muse, mutect2, varscan2
- TG | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 100/2110 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs745843270, COSV99602575; called by muse, mutect2
- TTLL2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200878719; called by muse, mutect2, varscan2
- USP45 | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | catalogued as COSV59681549; called by muse, mutect2, varscan2
- UTP6 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV55574327; called by muse, mutect2, varscan2
- ZNF711 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341473; called by muse, mutect2
- ZXDA | c.959A>C p.H320P | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62388366; called by muse, mutect2, varscan2
- ARFGAP2 | c.1439_1440del p.L480Rfs*13 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | called by mutect2, pindel, varscan2
- DAAM2 | c.3019_3022dup p.R1008Pfs*19 (on ENST00000274867 / NM_001201427.2; = p.R1007Pfs*19 on NM_015345.3) | Frame Shift Ins (INS) | VAF 18/168 reads (11%) | called by mutect2, pindel, varscan2
- TMEM95 | c.98_102del p.R33Lfs*24 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- ADCK2 | c.1035C>T p.S345= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV99301807; called by muse, mutect2
- ARFGAP2 | c.1113C>T p.S371= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100125647; called by muse, mutect2
- DCDC1 | c.2511T>C p.G837= | Silent (SNP) | VAF 99/258 reads (38%) | catalogued as COSV100663999; called by muse, mutect2
- LOXL4 | c.2082C>T p.I694= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV53257857; called by muse, mutect2, varscan2
- MMP3 | c.831G>C p.T277= | Silent (SNP) | VAF 142/481 reads (30%) | catalogued as COSV55405782, COSV55407008; called by muse, mutect2, varscan2
- NOTCH3 | c.5304G>T p.L1768= | Silent (SNP) | VAF 81/544 reads (15%) | catalogued as COSV54640650; called by muse, mutect2, varscan2
- SMARCA4 | c.3324C>T p.L1108= | Silent (SNP) | VAF 140/483 reads (29%) | catalogued as COSV60801793; called by muse, mutect2, varscan2
- SRRT | c.1098C>T p.S366= | Silent (SNP) | VAF 118/325 reads (36%) | catalogued as rs1469179161, COSV61453455; called by muse, mutect2, varscan2
- TBX22 | c.291A>G p.Q97= | Silent (SNP) | VAF 184/527 reads (35%) | catalogued as rs776595410, COSV100960914; called by muse, mutect2, varscan2
- TENM2 | c.1596C>A p.T532= (on ENST00000518659 / NM_001122679.2; = p.T300= on NM_001080428.3) | Silent (SNP) | VAF 155/577 reads (27%) | catalogued as COSV69130890, COSV69135629; called by muse, mutect2, varscan2
- VPS13D | c.2196T>A p.V732= | Silent (SNP) | VAF 85/514 reads (17%) | catalogued as COSV50654441; called by muse, mutect2, varscan2
- C12orf76 | n.743G>A | RNA (SNP) | VAF 39/154 reads (25%) | catalogued as rs371803112; called by muse, mutect2, varscan2
- RNF217-AS1 | n.4347dup | RNA (INS) | VAF 48/235 reads (20%) | catalogued as rs1228255792; called by pindel, varscan2
